Somatic mutation profile of tumor specimen TCGA-SB-A76C-01A (aliquot TCGA-SB-A76C-01A-11D-A435-10) from TCGA case TCGA-SB-A76C, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 38.4 years (14,023 days).
Specimen TCGA-SB-A76C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af727068-fce4-4328-8ec6-ce9bd7562df3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SB-A76C-10A (Blood Derived Normal), aliquot TCGA-SB-A76C-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5dd1ccf0-2376-408d-8536-dd76c4b9796f

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, Frame Shift Del 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 36/211 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BTN2A2 | c.382C>A p.R128S | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.639); catalogued as COSV61857567, COSV61857960; called by muse, mutect2, varscan2
- CENPP | c.137A>G p.N46S | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs770185935; called by muse, mutect2, varscan2
- CFHR4 | c.1525C>A p.P509T (on ENST00000367416 / NM_001201551.2; = p.P263T on NM_006684.5) | Missense Mutation (SNP) | VAF 82/632 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756854486; called by muse, mutect2
- MTO1 | c.6C>G p.F2L | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV100940595; called by muse, mutect2, varscan2
- SLC8B1 | c.38G>A p.S13N | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs776575003; called by muse, mutect2, varscan2
- ELL3 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FRMPD2 | c.1918C>A p.Q640K | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.029); called by muse, mutect2
- FUS | c.1509_1510del p.G504Wfs*12 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | called by pindel, varscan2
- OTUD6B | c.739_742del p.A247Ifs*6 | Frame Shift Del (DEL) | VAF 33/293 reads (11%) | called by mutect2, pindel, varscan2
- PCDHA6 | c.622C>T p.H208Y | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- ZNF836 | c.2788C>G p.L930V | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSF2RB | c.858G>A p.E286= | Silent (SNP) | VAF 20/44 reads (45%) | called by muse, mutect2, varscan2
- ZNF396 | c.975T>C p.H325= | Silent (SNP) | VAF 37/99 reads (37%) | catalogued as rs756597684; called by muse, mutect2, varscan2
- ZNF649 | c.585G>A p.E195= | Silent (SNP) | VAF 37/160 reads (23%) | called by muse, mutect2, varscan2
- CCDC144A | c.3372+1994C>G | Intron (SNP) | VAF 5/49 reads (10%) | catalogued as rs1404400643; called by muse, mutect2, varscan2
